Somatic mutation profile of tumor specimen MP2PRT-PARTLU-TMP1-A (aliquot MP2PRT-PARTLU-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PARTLU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,532 days).
Specimen MP2PRT-PARTLU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 981a7914-d291-48ac-85fb-6d095ef7fa53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTLU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTLU-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eaecbd5b-1b56-4b5a-be86-132c71eaee3f

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 14, 3'UTR 1, RNA 1, Splice Region 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 37/222 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ADAMTS1 | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 151/635 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs144295160; called by muse, mutect2, varscan2
- ARMC8 | c.193A>C p.R65= (on ENST00000469044 / NM_001363941.2; = p.R51= on NM_014154.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 13/226 reads (6%) | catalogued as rs977682024; called by muse, mutect2
- C5orf52 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 92/737 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs756763224; called by muse, mutect2, varscan2
- CADM3 | c.599G>A p.R200Q (on ENST00000368125 / NM_001127173.3; = p.R234Q on NM_021189.5) | Missense Mutation (SNP) | VAF 111/481 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV63685836, COSV63686020; called by muse, mutect2, varscan2
- CARS2 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 28/624 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758217572, COSV57286099; called by muse, mutect2
- CILP2 | c.715A>C p.T239P | Missense Mutation (SNP) | VAF 83/447 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.489); catalogued as COSV99365355; called by muse, mutect2, varscan2
- COL11A2 | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 34/937 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100554005, COSV100554196; called by muse, mutect2
- COL5A3 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 153/345 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs773722641, COSV53405282; called by muse, mutect2, varscan2
- DNAH5 | c.7481C>T p.A2494V | Missense Mutation (SNP) | VAF 443/718 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1428862297, COSV99456591; called by muse, mutect2, varscan2
- ELFN1 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 24/611 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as rs1432726003, COSV70034638; called by muse, mutect2
- FNDC1 | c.2038G>A p.V680I | Missense Mutation (SNP) | VAF 40/814 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99795788; called by muse, mutect2
- HNF1B | c.564G>C p.Q188H | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs778161185; called by muse, mutect2
- IARS1 | c.1511A>G p.D504G | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65114604; called by muse, mutect2, varscan2
- NMRK2 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV51455175; called by muse, mutect2, varscan2
- PLLP | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs749138902; called by muse, mutect2
- RTN1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 18/602 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as rs866404816; called by muse, mutect2
- TEF | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 15/372 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs951545931; called by muse, mutect2
- UBR1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 94/362 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.084); catalogued as rs774341055, COSV51926731; called by muse, mutect2, varscan2
- UGT2B28 | c.796T>A p.F266I | Missense Mutation (SNP) | VAF 133/468 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100158869; called by muse, mutect2, varscan2
- UNC13C | c.3055C>A p.L1019I | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs76062035; called by muse, mutect2, varscan2
- UNC79 | c.2288C>T p.P763L (on ENST00000393151 / NM_001346218.2; = p.P586L on NM_020818.5) | Missense Mutation (SNP) | VAF 44/820 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); catalogued as rs754794892, COSV56390892; called by muse, mutect2
- WSCD2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 30/437 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs571473218; called by muse, mutect2
- ZNF518A | c.2611G>T p.D871Y | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV60153214; called by muse, mutect2
- C9orf64 | c.175G>C p.A59P | Missense Mutation (SNP) | VAF 45/635 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.399); called by muse, mutect2
- DACT1 | c.2335A>T p.S779C | Missense Mutation (SNP) | VAF 28/603 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DGKA | c.1820_1821insGATGGT p.G607_G608insMV | In Frame Ins (INS) | VAF 119/283 reads (42%) | called by mutect2, pindel, varscan2
- GPR142 | c.122A>G p.H41R | Missense Mutation (SNP) | VAF 17/561 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- HEY2 | c.472A>T p.S158C | Missense Mutation (SNP) | VAF 31/743 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- HIGD1B | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 38/401 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.175); called by muse, mutect2
- KHDC3L | c.19T>A p.F7I | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LSM14B | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MMP26 | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NLRP7 | c.1710G>T p.E570D | Missense Mutation (SNP) | VAF 270/599 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PAPLN | c.3046C>T p.P1016S (on ENST00000554301; = p.P989S on NM_173462.4) | Missense Mutation (SNP) | VAF 79/866 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); called by muse, mutect2
- PFAS | c.1544A>G p.H515R | Missense Mutation (SNP) | VAF 120/400 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHG7 | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0.019); called by muse, mutect2
- PRORP | c.425G>T p.S142I | Missense Mutation (SNP) | VAF 34/560 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- SPATA31E1 | c.2507A>T p.E836V | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNRC18 | c.8515G>A p.G2839S | Missense Mutation (SNP) | VAF 157/353 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TPH1 | c.1208C>A p.P403Q | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- AATK | c.1980C>T p.G660= (on ENST00000326724 / NM_001080395.3; = p.G557= on NM_004920.2) | Silent (SNP) | VAF 71/896 reads (8%) | catalogued as rs55881512, COSV58373585; called by muse, mutect2
- BX276092.9 | c.129T>C p.F43= | Silent (SNP) | VAF 46/306 reads (15%) | called by muse, mutect2, varscan2
- CLASRP | c.651G>A p.Q217= | Silent (SNP) | VAF 26/375 reads (7%) | catalogued as rs1305485653; called by muse, mutect2
- CSMD1 | c.5361C>T p.N1787= (on ENST00000520002; = p.N1786= on NM_033225.6) | Silent (SNP) | VAF 92/261 reads (35%) | catalogued as rs34443453; called by muse, mutect2, varscan2
- HECW1 | c.3048T>A p.T1016= | Silent (SNP) | VAF 24/314 reads (8%) | called by muse, mutect2
- IQANK1 | c.363G>A p.Q121= | Silent (SNP) | VAF 31/549 reads (6%) | called by muse, mutect2
- KIF1B | c.4731A>T p.R1577= (on ENST00000377086 / NM_001365952.1; = p.R1531= on NM_015074.3) | Silent (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- NPAS2 | c.249A>G p.E83= | Silent (SNP) | VAF 37/224 reads (17%) | called by muse, mutect2, varscan2
- SCARA3 | c.138G>A p.Q46= | Silent (SNP) | VAF 12/195 reads (6%) | catalogued as rs1410002792; called by muse, mutect2
- SLC6A5 | c.1881C>T p.Y627= | Silent (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- SPEG | c.2430C>T p.T810= | Silent (SNP) | VAF 51/324 reads (16%) | catalogued as rs755942646; called by muse, mutect2, varscan2
- SPTLC3 | c.585G>T p.V195= | Silent (SNP) | VAF 21/247 reads (9%) | called by muse, mutect2
- SSH3 | c.174A>C p.A58= | Silent (SNP) | VAF 132/294 reads (45%) | called by muse, mutect2, varscan2
- TSHZ3 | c.621C>A p.I207= | Silent (SNP) | VAF 26/411 reads (6%) | catalogued as COSV53675470; called by muse, mutect2
- CCDC140 | n.748C>T | RNA (SNP) | VAF 81/381 reads (21%) | catalogued as rs986104219, COSV54676461; called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20893428 G>A | 3'Flank (SNP) | VAF 20/328 reads (6%) | catalogued as rs923128570; called by muse, mutect2
- WDR64 | c.*861A>C | 3'UTR (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
